CCDI case PBCFVW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/941c3c37-bab0-415a-9709-8ae9b06a667c

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 12.2 years (4,465 days).

Biospecimens (3 samples)
- Sample 0DQZ3M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQZ4I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DQZ4W: Tissue type: Tumor; Specimen type: Solid Tissue.
